Somatic mutation profile of tumor specimen ALCH-AE5J-TTP1-A (aliquot ALCH-AE5J-TTP1-A-1-0-D-A604-36) from ALCHEMIST case ALCH-AE5J, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.1 years (23,794 days).
Specimen ALCH-AE5J-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8e24fa6-c829-46ae-ad17-dadc2175f411.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE5J-NB1-A (Blood Derived Normal), aliquot ALCH-AE5J-NB1-A-1-0-D-A604-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8afb5e39-5393-41dc-ad61-45c64645b51b

The open-access MAF lists 226 somatic variants for this specimen: 160 protein-altering or splice-affecting, 40 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 40, Intron 13, Nonsense Mutation 10, Splice Site 6, RNA 5, 3'UTR 3, 5'UTR 3, Splice Region 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXL2 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 40/534 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1057516145; ClinVar: likely pathogenic; called by muse, mutect2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 73/549 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA4 | c.1997C>A p.S666Y | Missense Mutation (SNP) | VAF 29/596 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64677458; called by muse, mutect2
- ABCB8 | c.568G>A p.E190K (on ENST00000297504 / NM_001282291.2; = p.E173K on NM_007188.5) | Missense Mutation (SNP) | VAF 15/340 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.444); catalogued as rs1274126666, COSV52502894; called by muse, mutect2
- BRINP2 | c.2217C>A p.D739E | Missense Mutation (SNP) | VAF 16/309 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs912334622; called by muse, mutect2
- CLCN4 | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.612); catalogued as rs1064796023, COSV66465686; ClinVar: uncertain significance; called by muse, mutect2
- DISC1 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 21/676 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.288); catalogued as rs1452775697, COSV54418421; called by muse, mutect2
- DLG3 | c.2077G>T p.E693* (on ENST00000374360 / NM_021120.4; = p.E388* on NM_020730.3) | Nonsense Mutation (SNP) | VAF 14/98 reads (14%) | catalogued as COSV99529470; called by muse, mutect2, varscan2
- DMD | c.5503C>A p.Q1835K | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs1225638867; called by muse, mutect2
- DSG4 | c.153G>T p.W51C | Missense Mutation (SNP) | VAF 62/718 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748670675; called by muse, mutect2
- ENPP7 | c.363C>A p.N121K | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV100093760; called by muse, mutect2
- EPHB6 | c.165+1G>T p.X55_splice | Splice Site (SNP) | VAF 26/665 reads (4%) | catalogued as COSV67417564; called by muse, mutect2
- FGB | c.952C>A p.L318I | Missense Mutation (SNP) | VAF 23/512 reads (4%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.007); catalogued as COSV100122523, COSV57417357; called by muse, mutect2
- GATA3 | c.1190C>A p.S397Y | Missense Mutation (SNP) | VAF 39/803 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV60515663, COSV60523843; called by muse, mutect2
- GBX1 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs1218920341; called by muse, mutect2
- HERC6 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 25/569 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99986852; called by muse, mutect2
- HOXB13 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51704482; called by muse, mutect2
- JMJD4 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.017); catalogued as COSV59919211; called by muse, mutect2
- KDM6A | c.3458G>T p.C1153F | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65047763; called by muse, mutect2
- KIF26A | c.5525G>A p.R1842Q | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs367630936, COSV59469786; called by muse, mutect2, varscan2
- KLC4 | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV52438105, COSV99431730; called by muse, mutect2, varscan2
- LDB3 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 28/754 reads (4%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as rs1421438023; called by muse, mutect2
- MYH6 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 34/385 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV62452091; called by muse, mutect2
- NDUFAB1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs944684205, COSV50287418; called by muse, mutect2
- NEB | c.14628+1G>T p.X4876_splice | Splice Site (SNP) | VAF 20/290 reads (7%) | catalogued as COSV51426477; called by muse, mutect2
- NHS | c.761C>A p.A254D | Missense Mutation (SNP) | VAF 36/424 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.146); catalogued as rs1372273044; called by muse, mutect2
- OCA2 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 64/593 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs750843354, COSV62343651; called by muse, mutect2, varscan2
- OR2L5 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 34/536 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV62364630; called by muse, mutect2
- OR5AS1 | c.488C>A p.T163K | Missense Mutation (SNP) | VAF 42/562 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV57981301; called by muse, mutect2
- PLCH1 | c.350G>A p.R117H (on ENST00000340059 / NM_001130960.2; = p.R129H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/370 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs867310741, COSV58191309; called by muse, mutect2
- PLXNB2 | c.2339C>T p.A780V | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1157753906; called by muse, mutect2
- PTPRT | c.2667C>G p.F889L | Missense Mutation (SNP) | VAF 38/400 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV61965949; called by muse, mutect2
- REPIN1 | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV68293090; called by muse, mutect2
- RTL1 | c.1119G>T p.E373D | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as rs531395680, COSV66017504; called by muse, mutect2, varscan2
- RUFY4 | c.1702G>T p.A568S | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV60248546; called by muse, mutect2
- SH2B1 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59468057; called by muse, mutect2
- URI1 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 23/544 reads (4%) | catalogued as COSV56351616; called by muse, mutect2
- WDR17 | c.2048C>T p.T683I | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1379567283; called by muse, mutect2
- ZNF148 | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 19/312 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV100642049; called by muse, mutect2
- ZSCAN4 | c.176G>T p.R59M | Missense Mutation (SNP) | VAF 12/239 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV104402146; called by muse, mutect2
- ZSWIM8 | c.3114G>C p.Q1038H (on ENST00000605216 / NM_001242487.2; = p.Q1043H on NM_015037.3) | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV67131106; called by muse, mutect2
- ABCG8 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 16/432 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0.006); called by muse, mutect2
- ABL2 | c.3109G>T p.G1037W (on ENST00000502732 / NM_007314.4; = p.G1022W on NM_005158.5) | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2
- ACKR1 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 24/293 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- ACTN2 | c.1053G>C p.K351N | Missense Mutation (SNP) | VAF 23/441 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- ADAMTS2 | c.2088G>A p.K696= | Splice Region (SNP) | VAF 18/559 reads (3%) | called by muse, mutect2
- ADNP2 | c.145C>G p.H49D | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- ADRB3 | c.84T>A p.S28R | Missense Mutation (SNP) | VAF 25/302 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- AHSG | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.251); called by muse, varscan2
- AUTS2 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.19); called by muse, mutect2
- BPNT2 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 26/575 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2
- CCNE1 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.408); called by muse, mutect2
- CFH | c.169A>T p.R57* | Nonsense Mutation (SNP) | VAF 28/474 reads (6%) | called by muse, mutect2
- CHRNA9 | c.1139C>A p.S380Y | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2
- CNTNAP2 | c.1498+1G>C p.X500_splice | Splice Site (SNP) | VAF 17/400 reads (4%) | called by muse, mutect2
- COL5A2 | c.1915G>T p.G639W | Missense Mutation (SNP) | VAF 26/751 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL9A3 | c.1401+8C>A | Splice Region (SNP) | VAF 42/638 reads (7%) | called by muse, mutect2
- CPAMD8 | c.3194G>A p.G1065E (on ENST00000651564; = p.G1018E on NM_015692.5) | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- CPS1 | c.4139A>T p.Q1380L | Missense Mutation (SNP) | VAF 22/558 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2
- CSMD3 | c.9526C>A p.P3176T (on ENST00000297405 / NM_001363185.1; = p.P3007T on NM_052900.3) | Missense Mutation (SNP) | VAF 45/660 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2
- CSRNP3 | c.1084C>A p.Q362K | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); called by muse, mutect2
- CTNNA3 | c.2312A>T p.Q771L | Missense Mutation (SNP) | VAF 12/223 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.131); called by muse, mutect2
- DBP | c.140-2A>T p.X47_splice | Splice Site (SNP) | VAF 13/135 reads (10%) | called by muse, mutect2, varscan2
- DDX42 | c.2750A>G p.D917G | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- DOCK2 | c.2565C>A p.D855E | Missense Mutation (SNP) | VAF 13/294 reads (4%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.967); called by muse, mutect2
- DSC3 | c.1140T>A p.D380E | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ECPAS | c.4096G>T p.G1366C | Missense Mutation (SNP) | VAF 29/474 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EEF1AKMT3 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 21/506 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FANCB | c.551T>A p.L184* | Nonsense Mutation (SNP) | VAF 22/137 reads (16%) | called by muse, mutect2, varscan2
- FGD1 | c.1006G>C p.D336H | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FMO3 | c.1206G>T p.M402I | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- FOLH1 | c.611G>T p.R204I | Missense Mutation (SNP) | VAF 21/229 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FOXL1 | c.318C>A p.C106* | Nonsense Mutation (SNP) | VAF 65/712 reads (9%) | called by muse, mutect2
- FREM2 | c.5496G>T p.Q1832H | Missense Mutation (SNP) | VAF 19/453 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GABRG2 | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 31/460 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- GEMIN8 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 18/260 reads (7%) | called by muse, mutect2
- GGN | c.1432C>A p.P478T | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- GON7 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2
- GPR174 | c.308A>T p.Y103F | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPX6 | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- GRIA3 | c.1239C>G p.I413M | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- HAUS6 | c.1522C>G p.P508A | Missense Mutation (SNP) | VAF 23/299 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.058); called by muse, mutect2
- HDAC9 | c.1018C>A p.Q340K | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.009); called by muse, mutect2
- HIVEP2 | c.2612A>T p.Q871L | Missense Mutation (SNP) | VAF 37/624 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- HLF | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HYDIN | c.1985G>T p.C662F | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IFITM3 | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- IFT88 | c.291G>T p.Q97H (on ENST00000319980 / NM_001318493.2; = p.Q88H on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/437 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- IL7R | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 26/432 reads (6%) | called by muse, mutect2
- ILDR2 | c.505A>T p.T169S | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.412); called by muse, mutect2
- ITPRID2 | c.985G>C p.V329L | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.011); called by muse, mutect2
- JARID2 | c.1059G>C p.K353N | Missense Mutation (SNP) | VAF 19/599 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.343); called by muse, mutect2
- JCAD | c.2198A>T p.H733L | Missense Mutation (SNP) | VAF 36/512 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.033); called by muse, mutect2
- KCNC2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.009); called by muse, mutect2
- KIAA2012 | c.833C>A p.T278K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- KLHDC10 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KLHDC7A | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL5 | c.1143G>C p.E381D | Missense Mutation (SNP) | VAF 40/610 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- KLRF2 | c.242A>T p.D81V | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2
- LIG1 | c.2677-1G>T p.X893_splice | Splice Site (SNP) | VAF 25/566 reads (4%) | called by muse, mutect2
- LIN28B | c.211A>T p.M71L | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); called by muse, varscan2
- MCM10 | c.508G>T p.E170* (on ENST00000484800 / NM_182751.3; = p.E169* on NM_018518.5) | Nonsense Mutation (SNP) | VAF 12/308 reads (4%) | called by muse, mutect2
- MCTP2 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 27/318 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- MLH3 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 33/411 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MRC1 | c.1319G>A p.G440E | Missense Mutation (SNP) | VAF 22/722 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2
- MUC15 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 18/475 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2
- N4BP3 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2
- NACAD | c.3868C>A p.P1290T | Missense Mutation (SNP) | VAF 23/389 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2
- NCAPG2 | c.2916G>T p.Q972H | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2
- NPAP1 | c.2431T>G p.S811A | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- NPFFR2 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 16/455 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- NR1D1 | c.999T>G p.N333K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.027); called by muse, mutect2
- NR1H3 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR14A2 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR14C36 | c.726C>A p.H242Q | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR51E1 | c.33T>A p.S11R | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.28); called by muse, mutect2
- OR52H1 | c.360G>T p.M120I (on ENST00000322653; = p.M126I on NM_001005289.1) | Missense Mutation (SNP) | VAF 25/342 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR52H1 | c.359T>A p.M120K (on ENST00000322653; = p.M126K on NM_001005289.1) | Missense Mutation (SNP) | VAF 25/345 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR52K2 | c.321C>A p.H107Q | Missense Mutation (SNP) | VAF 17/277 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- OTC | c.843C>A p.F281L | Missense Mutation (SNP) | VAF 43/321 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PAGE1 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- PAX7 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PCDH15 | c.5053G>A p.E1685K | Missense Mutation (SNP) | VAF 22/383 reads (6%) | SIFT tolerated, low confidence (0.33); called by muse, mutect2
- PCDH7 | c.1176G>T p.Q392H | Missense Mutation (SNP) | VAF 34/433 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.608); called by muse, mutect2
- PCDHB3 | c.1535A>T p.H512L | Missense Mutation (SNP) | VAF 94/1384 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.211); called by muse, mutect2
- PDHA2 | c.401C>A p.A134E | Missense Mutation (SNP) | VAF 20/467 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- PHC3 | c.1243C>T p.H415Y (on ENST00000494943 / NM_001308116.2; = p.H427Y on NM_024947.4) | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- PKHD1 | c.11332G>T p.G3778* | Nonsense Mutation (SNP) | VAF 24/246 reads (10%) | called by muse, mutect2
- PMFBP1 | c.21G>C p.E7D | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- PSD2 | c.2288C>T p.T763I | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2
- RAD54L2 | c.1114A>G p.K372E | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.312); called by muse, mutect2
- RANBP2 | c.1784A>T p.Q595L | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RELN | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 30/591 reads (5%) | called by muse, mutect2
- RTL6 | c.340G>C p.G114R | Missense Mutation (SNP) | VAF 22/299 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.716); called by muse, mutect2
- SCN3A | c.5335G>C p.E1779Q | Missense Mutation (SNP) | VAF 26/692 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SECISBP2 | c.77G>C p.R26T | Missense Mutation (SNP) | VAF 29/836 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2
- SGIP1 | c.1486C>A p.P496T | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SH2D7 | c.612T>A p.S204R | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2
- SLC4A4 | c.2323G>A p.E775K (on ENST00000264485 / NM_001098484.3; = p.E731K on NM_003759.4) | Missense Mutation (SNP) | VAF 17/540 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SPPL2A | c.1288A>G p.T430A | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2
- SPTA1 | c.3517G>T p.D1173Y | Missense Mutation (SNP) | VAF 18/455 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- SPTB | c.4137G>T p.R1379S | Missense Mutation (SNP) | VAF 32/502 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- STRADB | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 17/376 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by muse, mutect2
- SVOPL | c.1354-1G>T p.X452_splice (on ENST00000419765; = p.X300_splice on NM_174959.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2, varscan2
- SYK | c.342G>T p.Q114H | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- TBX5 | c.1190G>T p.S397I | Missense Mutation (SNP) | VAF 34/784 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- TMEM63C | c.915G>T p.W305C | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOPAZ1 | c.2560C>A p.L854I | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- TPD52L3 | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 71/597 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSPAN6 | c.635T>A p.V212D | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- USH2A | c.7850T>C p.V2617A | Missense Mutation (SNP) | VAF 25/598 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2
- VCAN | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 22/499 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- WDR20 | c.170A>T p.D57V | Missense Mutation (SNP) | VAF 49/907 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2
- WDR87 | c.3404C>T p.S1135F | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2
- ZEB1 | c.2998G>C p.E1000Q | Missense Mutation (SNP) | VAF 19/551 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.261); called by muse, mutect2
- ZIC5 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 38/1106 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2
- ZIC5 | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 39/1094 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.826); called by muse, mutect2
- ZNF106 | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2
- ZNF536 | c.2893C>A p.Q965K | Missense Mutation (SNP) | VAF 19/330 reads (6%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.006); called by muse, mutect2
- ZSCAN4 | c.586T>A p.W196R | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- ADH7 | c.72A>T p.A24= | Silent (SNP) | VAF 14/302 reads (5%) | called by muse, mutect2
- B3GALT4 | c.321G>T p.T107= | Silent (SNP) | VAF 13/129 reads (10%) | called by muse, mutect2, varscan2
- BEST2 | c.510G>A p.K170= | Silent (SNP) | VAF 21/254 reads (8%) | called by muse, mutect2
- CD19 | c.123G>T p.G41= | Silent (SNP) | VAF 13/249 reads (5%) | called by muse, mutect2
- CPT1C | c.48G>T p.S16= | Silent (SNP) | VAF 18/331 reads (5%) | called by muse, mutect2
- CUL9 | c.3879G>T p.V1293= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- F8 | c.3546C>G p.L1182= | Silent (SNP) | VAF 13/121 reads (11%) | called by muse, mutect2, varscan2
- FAM83C | c.789G>T p.V263= | Silent (SNP) | VAF 18/252 reads (7%) | called by muse, mutect2
- FAT3 | c.10515G>T p.S3505= | Silent (SNP) | VAF 22/195 reads (11%) | catalogued as COSV99965228; called by muse, mutect2, varscan2
- FBLN5 | c.63G>A p.G21= | Silent (SNP) | VAF 28/430 reads (7%) | catalogued as rs569683263; called by muse, mutect2
- GCGR | c.918C>A p.I306= | Silent (SNP) | VAF 24/304 reads (8%) | called by muse, mutect2
- IGSF1 | c.3372G>A p.V1124= | Silent (SNP) | VAF 11/272 reads (4%) | called by muse, mutect2
- IRX4 | c.765G>T p.L255= | Silent (SNP) | VAF 121/829 reads (15%) | called by muse, mutect2, varscan2
- LALBA | c.138C>T p.I46= | Silent (SNP) | VAF 26/314 reads (8%) | called by muse, mutect2
- MAP9 | c.330C>T p.I110= | Silent (SNP) | VAF 16/468 reads (3%) | called by muse, mutect2
- MMP16 | c.333C>A p.S111= | Silent (SNP) | VAF 33/344 reads (10%) | called by muse, mutect2
- MOCOS | c.903A>T p.G301= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- MUC16 | c.36132C>A p.A12044= | Silent (SNP) | VAF 28/288 reads (10%) | catalogued as COSV67466011; called by muse, mutect2
- N4BP1 | c.2298A>T p.R766= | Silent (SNP) | VAF 12/241 reads (5%) | called by muse, mutect2
- OR4D2 | c.486G>T p.L162= | Silent (SNP) | VAF 31/576 reads (5%) | called by muse, mutect2
- OTOP2 | c.1170G>A p.V390= | Silent (SNP) | VAF 15/294 reads (5%) | called by muse, mutect2
- PDE4DIP | c.6708C>T p.S2236= | Silent (SNP) | VAF 11/249 reads (4%) | catalogued as rs1553632434; called by muse, mutect2
- PGR | c.210C>A p.S70= | Silent (SNP) | VAF 13/336 reads (4%) | catalogued as COSV54797161; called by muse, mutect2
- PHLDB3 | c.906G>T p.R302= | Silent (SNP) | VAF 21/246 reads (9%) | called by muse, mutect2
- PKD1L2 | c.2658G>A p.L886= | Silent (SNP) | VAF 13/115 reads (11%) | called by muse, mutect2, varscan2
- PTGER3 | c.387C>T p.L129= | Silent (SNP) | VAF 19/419 reads (5%) | called by muse, mutect2
- PTPN11 | c.1347C>T p.I449= | Silent (SNP) | VAF 22/418 reads (5%) | called by muse, mutect2
- SF3A1 | c.600A>T p.P200= | Silent (SNP) | VAF 31/203 reads (15%) | called by muse, mutect2, varscan2
- SLC35G5 | c.660A>T p.P220= | Silent (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- SLIT2 | c.4485G>A p.L1495= | Silent (SNP) | VAF 28/359 reads (8%) | catalogued as COSV56580021; called by muse, mutect2
- SNX31 | c.1062C>T p.C354= | Silent (SNP) | VAF 11/204 reads (5%) | called by muse, mutect2
- TADA1 | c.114C>T p.I38= | Silent (SNP) | VAF 15/275 reads (5%) | called by muse, mutect2
- TENM2 | c.1101C>T p.P367= (on ENST00000518659 / NM_001122679.2; = p.P176= on NM_001080428.3) | Silent (SNP) | VAF 19/444 reads (4%) | called by muse, mutect2
- TFAP2B | c.1155C>A p.P385= | Silent (SNP) | VAF 20/462 reads (4%) | catalogued as COSV53832394; called by muse, mutect2
- TNNC1 | c.384C>T p.I128= | Silent (SNP) | VAF 21/639 reads (3%) | called by muse, mutect2
- TOP2B | c.4317A>G p.K1439= (on ENST00000264331 / NM_001330700.2; = p.K1434= on NM_001068.3) | Silent (SNP) | VAF 9/127 reads (7%) | called by muse, mutect2
- TRIM42 | c.1719C>G p.T573= | Silent (SNP) | VAF 14/292 reads (5%) | called by muse, mutect2
- USH2A | c.7035C>A p.A2345= | Silent (SNP) | VAF 30/324 reads (9%) | called by muse, mutect2
- ZKSCAN1 | c.231G>A p.L77= | Silent (SNP) | VAF 20/347 reads (6%) | called by muse, mutect2
- ZMYM3 | c.1668C>T p.P556= | Silent (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- ADAM15 | c.*8G>T | 3'UTR (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- ADCY10P1 | n.3707G>T | RNA (SNP) | VAF 16/376 reads (4%) | called by muse, mutect2
- ATP1A2 | c.3034+38C>A | Intron (SNP) | VAF 14/276 reads (5%) | called by muse, mutect2
- BTNL9 | c.887-357G>T | Intron (SNP) | VAF 22/486 reads (5%) | called by muse, mutect2
- CHRNB4 | c.*56G>T | 3'UTR (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56812035 G>T | 3'Flank (SNP) | VAF 16/330 reads (5%) | catalogued as rs1233972280; called by muse, mutect2
- CICP28 | chr7:56812036 G>T | 3'Flank (SNP) | VAF 16/326 reads (5%) | called by muse, mutect2
- FAM183BP | n.833C>A | RNA (SNP) | VAF 28/258 reads (11%) | called by muse, mutect2, varscan2
- FCAR | c.-23G>A | 5'UTR (SNP) | VAF 13/166 reads (8%) | catalogued as rs774493601, COSV100629164; called by muse, mutect2
- FRMD4A | c.46-149220G>C | Intron (SNP) | VAF 16/327 reads (5%) | called by muse, mutect2
- GH2 | c.456+105A>G | Intron (SNP) | VAF 19/335 reads (6%) | called by muse, mutect2
- LHX1 | c.675+81G>C | Intron (SNP) | VAF 22/690 reads (3%) | called by muse, mutect2
- MIR1275 | n.75G>A | RNA (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- NBPF22P | n.1061T>A | RNA (SNP) | VAF 25/563 reads (4%) | called by muse, mutect2
- NTRK1 | c.1502-50C>A | Intron (SNP) | VAF 18/266 reads (7%) | catalogued as rs1347860207; called by muse, mutect2
- PIPSL | n.1270G>T | RNA (SNP) | VAF 14/412 reads (3%) | called by muse, mutect2
- PPIB | c.-24G>T | 5'UTR (SNP) | VAF 26/518 reads (5%) | called by muse, mutect2
- SIDT1 | c.1967-1023G>T | Intron (SNP) | VAF 24/302 reads (8%) | called by muse, mutect2
- SPTAN1 | c.6265-40G>T | Intron (SNP) | VAF 17/456 reads (4%) | called by muse, mutect2
- TAF1D | c.-154G>T | 5'UTR (SNP) | VAF 26/330 reads (8%) | called by muse, mutect2
- THOC1 | c.128+11G>A | Intron (SNP) | VAF 14/210 reads (7%) | called by muse, mutect2
- TRPM3 | c.979+16653G>T | Intron (SNP) | VAF 18/380 reads (5%) | catalogued as COSV100678776, COSV62467694; called by muse, mutect2
- WWOX | c.*240G>T | 3'UTR (SNP) | VAF 39/632 reads (6%) | called by muse, mutect2
- YAF2 | c.153-37407C>T | Intron (SNP) | VAF 15/262 reads (6%) | called by muse, mutect2
- ZEB2 | c.73+5091G>T | Intron (SNP) | VAF 21/240 reads (9%) | called by muse, mutect2
- ZEB2 | c.73+4893G>T | Intron (SNP) | VAF 20/359 reads (6%) | called by muse, mutect2
